Gene-level copy-number profile of tumor specimen HCM-CSHL-0586-C32-01A from HCMI case HCM-CSHL-0586-C32, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0586-C32-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 59161b8c-6cf7-4af9-bb80-5eb73bb039c9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0586-C32-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/48b17eea-4b50-4fac-ae1c-227746d3b66f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 541; copy number 1: 7,544; copy number 2: 41,804; copy number 3: 6,722; copy number 4: 1,916; copy number 5: 44; copy number 6: 53; copy number 7: 52; copy number 8: 12; copy number 9: 118; copy number 10: 13; copy number 11: 22; copy number 12: 4; copy number 18: 3; copy number 20: 16; copy number 21: 14; copy number 23: 11; copy number 28: 11.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–133,723, 11 genes (within-gene range 0–2): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3.
- chr8:8,086,022–8,086,765, 1 gene: AC105233.2.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr15:44,970,035–44,973,661, 2 genes (within-gene range 0–2): AC090888.2, RNU6-966P.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 373 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:16,916,359–17,346,152, 1 gene, copy number 5 (within-gene range 3–5): AHR.
- chr7:16,970,320–17,299,368, 1 gene, copy number 5 (within-gene range 3–5): AC073332.1.
- chr7:17,299,295–17,680,659, 5 genes, copy number 5: AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1.
- chr8:8,154,308–8,226,614, 3 genes, copy number 5: ENPP7P1, FAM85B, AC068020.1.
- chr8:117,794,490–118,622,112, 3 genes, copy number 5 (within-gene range 3–5): EXT1, SAMD12, AC023590.1.
- chr9:1,977,784–16,870,843, 181 genes, copy number 7–28 (within-gene range 3–40) (broad region; genes not listed).
- chr9:41,974,362–41,983,753, 2 genes, copy number 6: RBM17P3, CR788268.1.
- chr10:3,775,996–3,834,728, 2 genes, copy number 5: KLF6, LINC02639.
- chr13:73,399,031–73,661,891, 4 genes, copy number 6: AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr17:26,981,694–28,272,365, 54 genes, copy number 6–7: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9, LINC01992, AC005697.3, AC090287.1, AC090287.2, SNORA70, NLK, Vault, RPS29P22, AC061975.8, AC061975.7, PYY2, ERVE-1, AC061975.6, PPY2P, AC061975.2, AC061975.4, AC061975.1, AC061975.5.
- chr17:74,584,679–75,708,062, 63 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr18:3,025,069–4,455,307, 29 genes, copy number 5 (within-gene range 4–5): AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66.
- chr19:14,091,688–14,612,035, 25 genes, copy number 8–10: PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P, AC011509.2, AC011509.1, LINC01841, LINC01842, ADGRE5, AC008569.1, DDX39A, PKN1, AC008569.2, PTGER1, GIPC1, SNRPGP15, DNAJB1, TECR, MIR639, NDUFB7, CLEC17A, RN7SL337P, RN7SL842P.

Autosomal genes at a single copy (total copy number 1): 5,199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
